CCDI case PBCUCN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/8be14a67-e6d2-4c24-bb0a-8db4120dfea3

Demographics
Sex at birth: female.

Biospecimens (3 samples)
- Sample 0E03UK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E03V5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0E03W1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
